Somatic mutation profile of tumor specimen C3L-04483-54 (aliquot CPT0280240002) from CPTAC case C3L-04483, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 41.1 years (15,017 days).
Specimen C3L-04483-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3dc450a-ddfb-490e-800f-f152e65d75d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04483-52 (Buccal Cell Normal), aliquot CPT0280230001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2fc147c-9862-4400-a1ba-cbf025672b3e

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Frame Shift Del 1, Intron 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 84/192 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 73/182 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SRSF2 | c.284_307del p.P95_R102del | In Frame Del (DEL) | VAF 90/208 reads (43%) | hotspot (GDC flag); catalogued as rs766200080; called by mutect2, pindel
- CPS1 | c.4414del p.L1472Ffs*48 | Frame Shift Del (DEL) | VAF 114/319 reads (36%) | catalogued as rs755682125; called by mutect2, pindel, varscan2
- EXOSC2 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs375878809; called by muse, mutect2, varscan2
- FHDC1 | c.2792C>A p.P931H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.339); catalogued as COSV52599507; called by muse, mutect2, varscan2
- SYT14 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0.168); catalogued as rs796524658, COSV99655818; called by mutect2, varscan2
- GPR12 | c.644A>G p.Q215R | Missense Mutation (SNP) | VAF 146/316 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- HDAC7 | c.469C>T p.P157S (on ENST00000427332; = p.P196S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH15 | c.1002C>G p.Y334* | Nonsense Mutation (SNP) | VAF 84/185 reads (45%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.851A>G p.H284R | Missense Mutation (SNP) | VAF 62/154 reads (40%) | PolyPhen benign (0.227); called by muse, mutect2, varscan2
- RUNX1 | c.326A>T p.N109I (on ENST00000344691 / NM_001001890.3; = p.N136I on NM_001754.5) | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC12A9 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 110/268 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR9Q2 | c.264C>T p.H88= | Silent (SNP) | VAF 107/229 reads (47%) | catalogued as rs761516412, COSV100285496; called by muse, mutect2, varscan2
- PKHD1 | c.4818C>A p.V1606= | Silent (SNP) | VAF 70/195 reads (36%) | catalogued as COSV61860468, COSV61864906; called by muse, mutect2, varscan2
- REST | c.1389A>G p.E463= | Silent (SNP) | VAF 59/120 reads (49%) | called by muse, mutect2, varscan2
- SOX21 | c.651C>T p.A217= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1322837592, COSV65375485; called by mutect2, varscan2
- ATP10B | c.470+1189C>T | Intron (SNP) | VAF 45/96 reads (47%) | catalogued as rs1402543868, COSV58780456; called by muse, mutect2, varscan2
